Somatic mutation profile of tumor specimen TCGA-32-1980-01A (aliquot TCGA-32-1980-01A-01D-1696-08) from TCGA case TCGA-32-1980, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.5 years (26,467 days).
Specimen TCGA-32-1980-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 538ae17a-0dac-4a9e-a939-2474040310c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-1980-10A (Blood Derived Normal), aliquot TCGA-32-1980-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aff5eda3-29ea-41ad-9867-8f97b83593fa

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.6007-2A>G p.X2003_splice (on ENST00000358273 / NM_001042492.3; = p.X1982_splice on NM_000267.3) | Splice Site (SNP) | VAF 3/35 reads (9%) | catalogued as rs1555534595, CS000881, COSV62206308; ClinVar: pathogenic; called by muse, mutect2
- ARCN1 | c.902T>A p.I301N | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV50615431; called by muse, mutect2
- CFL2 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.142); catalogued as rs757526740, COSV53310918; called by muse, mutect2, varscan2
- F10 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765479486, CM010240, COSV65022025; called by muse, mutect2, varscan2
- FAT4 | c.6844G>A p.V2282M | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1479135467, COSV58689654; called by muse, mutect2
- NHLRC1 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61481579; called by muse, mutect2, varscan2
- NLRP4 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as COSV56715442; called by muse, mutect2
- OR2J3 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs775212459, COSV65848879; called by muse, mutect2
- OR9A4 | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as COSV71885570; called by muse, mutect2, varscan2
- TTN | c.6427G>C p.A2143P (on ENST00000591111; = p.A2097P on NM_003319.4) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | PolyPhen benign (0); catalogued as COSV60114129; called by muse, mutect2
- REST | c.282A>G p.E94= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV58361065; called by muse, mutect2
- ZNF782 | c.975C>G p.L325= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs1171924003, COSV56653055, COSV56654114; called by muse, mutect2, varscan2
